Gene-level copy-number profile of tumor specimen TCGA-77-A5G6-01A from TCGA case TCGA-77-A5G6, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.3 years (24,215 days).
Specimen TCGA-77-A5G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b5423bd2-9630-4aed-8e48-b7ccf19c4223.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-A5G6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b02a21e-7fd2-4044-8094-4c1d12b5577f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 887; copy number 2: 18,681; copy number 3: 17,503; copy number 4: 9,949; copy number 5: 7,620; copy number 6: 2,924; copy number 7: 332; copy number 8: 640; copy number 9: 435; copy number 10: 715; copy number 11: 12; copy number 15: 4; copy number 16: 8; copy number 18: 5; copy number 22: 16; copy number 28: 24; copy number 32: 7; copy number 36: 9; copy number 37: 1; copy number 38: 5; copy number 46: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-A5G6-01A-11D-A27J-01): tumor purity 0.7, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,512,115–22,824,213, 22 genes: MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,223 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,278,606–121,580,524, 127 genes, copy number 10 (broad region; genes not listed).
- chr3:114,314,500–115,147,288, 1 gene, copy number 8 (within-gene range 6–8): ZBTB20.
- chr3:114,684,580–198,222,513, 1,502 genes, copy number 8–10 (broad region; genes not listed).
- chr4:35,948,221–36,244,514, 1 gene, copy number 7 (within-gene range 4–7): ARAP2.
- chr4:36,244,116–39,782,792, 66 genes, copy number 7 (broad region; genes not listed).
- chr5:57,574,027–63,302,056, 66 genes, copy number 7–10 (broad region; genes not listed).
- chr6:106,271,634–107,051,586, 19 genes, copy number 36–46: U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1.
- chr6:108,041,409–108,165,854, 1 gene, copy number 9 (within-gene range 6–9): OSTM1.
- chr6:108,123,457–112,102,790, 91 genes, copy number 9–37 (broad region; genes not listed).
- chr7:70,972–989,640, 28 genes, copy number 7: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1.
- chr9:22,703,516–23,438,700, 1 gene, copy number 11 (within-gene range 0–11): AL391117.1.
- chr9:23,291,544–24,088,051, 11 genes, copy number 11: AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr11:6,713,536–7,657,127, 23 genes, copy number 7 (within-gene range 4–7): GVINP1, GVINP2, OR2AG2, OR2AG1, OR6A2, AC087280.2, AC087280.1, OR10A5, OR10A2, OR10A4, OR2D2, OR2D3, ZNF215, ZNF214, NLRP14, RBMXL2, AC027804.1, MIR302E, SYT9, AC107884.1, OLFML1, PPFIBP2, AC107884.2.
- chr11:12,904,817–15,481,893, 44 genes, copy number 7: AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1.
- chr11:29,713,909–30,017,030, 5 genes, copy number 7: AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4.
- chr11:131,370,478–132,336,822, 1 gene, copy number 32 (within-gene range 3–38): NTM.
- chr11:131,502,735–134,378,341, 35 genes, copy number 28–38 (within-gene range 6–38): AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2.
- chr11:134,945,118–135,075,908, 5 genes, copy number 18: AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr14:69,854,131–70,032,366, 1 gene, copy number 7 (within-gene range 3–7): SMOC1.
- chr14:72,515,407–73,040,914, 12 genes, copy number 7: AC004828.2, MIR7843, AC004828.1, DPF3, AL392024.1, Y_RNA, DCAF4, AC007160.1, AL442663.4, AL442663.1, ZFYVE1, RN7SL586P.
- chr14:75,079,353–75,955,079, 24 genes, copy number 7 (within-gene range 4–7): NEK9, HIF1AP1, AL049780.2, TMED10, AL691403.2, RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2, BATF, AC007182.1, FLVCR2, AC007182.2, RNA5SP387, AC007182.3, TTLL5, ERG28, AF107885.2, AF107885.1.
- chr14:75,958,097–75,983,011, 2 genes, copy number 7: TGFB3, TGFB3-AS1.
- chr14:79,661,666–79,791,263, 1 gene, copy number 9: AC008056.1.
- chr14:85,518,871–85,654,428, 3 genes, copy number 10: AL049775.1, AL049775.3, FLRT2.
- chr14:87,634,379–87,872,291, 3 genes, copy number 9: LINC02330, AL359237.1, AL136501.1.
- chr14:90,758,599–91,417,844, 12 genes, copy number 8 (within-gene range 4–8): AL122020.2, AL122020.1, LINC02321, RPS6KA5, DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, AL135818.3, CCDC88C.
- chr14:92,513,781–92,935,285, 6 genes, copy number 7: RIN3, LGMN, GOLGA5, LINC02833, LINC02287, CHGA.
- chr14:94,304,248–94,675,829, 16 genes, copy number 8 (within-gene range 4–8): SERPINA6, SERPINA2, SERPINA1, AL132708.1, SERPINA11, SERPINA9, SERPINA12, AL132990.1, SERPINA4, SERPINA5, AL049839.2, AL049839.3, SERPINA3, ADIPOR1P2, SERPINA13P, AL049839.1.
- chr14:96,275,046–97,217,778, 22 genes, copy number 8: AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, AL137786.2, LINC02299, AL137786.3, VRK1, LINC00618, AL049833.3, AL049833.4, AL049833.2, AL049833.1, LINC02304, AL158800.1.
- chr14:98,711,613–99,272,197, 10 genes, copy number 8: C14orf177, AL132796.1, AL132796.3, AL132796.2, RPL3P4, AL162151.2, AL162151.3, AL162151.1, BCL11B, AL109767.1.
- chr14:99,737,693–100,282,788, 14 genes, copy number 8 (within-gene range 4–8): EML1, RNU1-47P, VDAC3P1, EVL, AL133368.1, AL133368.2, AL157912.1, MIR151B, MIR342, DEGS2, AL133523.1, YY1, AL157871.5, MIR6764.
- chr14:106,657,725–106,875,071, 32 genes, copy number 7: IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV3-69-1, IGHV1-69-2, AC245369.21, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.
- chr16:68,358,327–68,448,508, 1 gene, copy number 9 (within-gene range 3–9): SMPD3.
- chr16:89,737,549–90,222,851, 23 genes, copy number 7 (within-gene range 3–7): FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr18:73,711,329–74,413,209, 14 genes, copy number 7–16: AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1, LINC01922.

Autosomal genes at a single copy (total copy number 1): 887. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
